Somatic mutation profile of tumor specimen TCGA-HT-A5RA-01A (aliquot TCGA-HT-A5RA-01A-11D-A289-08) from TCGA case TCGA-HT-A5RA, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 65.1 years (23,769 days).
Specimen TCGA-HT-A5RA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 542a5af8-1127-4e20-aea6-971e225ad873.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-A5RA-10A (Blood Derived Normal), aliquot TCGA-HT-A5RA-10A-01D-A289-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f22d1f1-9595-4b3a-93b0-a18e79fa4105

The open-access MAF lists 52 somatic variants for this specimen: 33 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 18, In Frame Del 1, 3'Flank 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADS | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 58/142 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as rs199633532, CM067634, COSV54368245; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADCK2 | c.127C>G p.L43V | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.825); catalogued as COSV50781617; called by muse, mutect2, varscan2
- C8B | c.940C>T p.H314Y | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as rs968552522, COSV64777885; called by muse, mutect2, varscan2
- CD200R1L | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.06); catalogued as rs369844409; called by muse, mutect2, varscan2
- CD22 | c.1381G>A p.A461T | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs370742313; called by muse, mutect2, varscan2
- EPPK1 | c.5798C>T p.A1933V | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs561179913, COSV73261464; called by muse, mutect2, varscan2
- EXOC1 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 27/62 reads (44%) | catalogued as COSV62120421, COSV62122495; called by muse, mutect2, varscan2
- FER1L6 | c.4658G>A p.R1553Q | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs533143433, COSV67550287; called by muse, mutect2, varscan2
- HSPB7 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 87/221 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs143274675, COSV58891860; called by muse, mutect2, varscan2
- HSPG2 | c.7216G>A p.V2406M | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1364243687, COSV65972242; called by muse, mutect2, varscan2
- KDM6A | c.3607G>A p.A1203T | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.137); catalogued as COSV65040398, COSV65040792; called by muse, mutect2, varscan2
- LTBP1 | c.3278A>G p.Q1093R (on ENST00000404816 / NM_206943.4; = p.Q767R on NM_000627.4) | Missense Mutation (SNP) | VAF 59/123 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV55379823; called by muse, mutect2, varscan2
- MAGEB6B | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 69/156 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as rs1354125609; called by muse, mutect2, varscan2
- MKNK1 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as rs1557814794, COSV57861440; called by muse, mutect2, varscan2
- NPAS3 | c.1189C>T p.R397C (on ENST00000356141 / NM_001164749.2; = p.R365C on NM_022123.3) | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60837091; called by muse, mutect2, varscan2
- PLEKHN1 | c.800G>A p.G267E (on ENST00000379409; = p.G215E on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.691); catalogued as COSV58022056; called by muse, mutect2, varscan2
- PTEN | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 58/89 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV64293130, COSV64294624; called by muse, mutect2, varscan2
- RUSC2 | c.1589C>A p.A530D | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as rs779999067, COSV63428773; called by muse, mutect2, varscan2
- SEC11C | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.185); catalogued as rs115898236, COSV55311471; called by muse, mutect2, varscan2
- SEPTIN7 | c.104A>G p.N35S | Missense Mutation (SNP) | VAF 71/164 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.156); catalogued as rs781017831, COSV63255201; called by muse, mutect2, varscan2
- SIPA1L3 | c.482G>A p.R161K | Missense Mutation (SNP) | VAF 79/245 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.116); catalogued as COSV55915280; called by muse, mutect2, varscan2
- SLC6A12 | c.466A>C p.T156P | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV62885233; called by muse, mutect2, varscan2
- TAS2R40 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 68/230 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.015); catalogued as rs772571667, COSV68818403; called by muse, mutect2, varscan2
- TELO2 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs769532584, COSV51978456; called by muse, mutect2, varscan2
- TRPV6 | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 89/274 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs146718533; called by muse, mutect2, varscan2
- TUBB4A | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 46/189 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV51156178; called by muse, mutect2, varscan2
- WAPL | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV53935610; called by muse, mutect2, varscan2
- ZAN | c.6412C>T p.R2138W | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs777285944, COSV61809889; called by muse, mutect2, varscan2
- ZBTB21 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs368914741, COSV100177261; called by muse, mutect2, varscan2
- ZCCHC12 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as rs1212891619, COSV59571293; called by muse, mutect2, varscan2
- ZNF331 | c.1249G>A p.G417R | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.921); catalogued as rs1196484537, COSV53477167; called by muse, mutect2, varscan2
- PTAR1 | c.412del p.E138Kfs*13 | Frame Shift Del (DEL) | VAF 15/32 reads (47%) | called by mutect2, pindel, varscan2
- SNAPIN | c.290_292del p.N97del | In Frame Del (DEL) | VAF 40/103 reads (39%) | called by pindel, varscan2
- ARHGEF15 | c.879C>T p.F293= | Silent (SNP) | VAF 35/96 reads (36%) | catalogued as rs764749566, COSV62725339; ClinVar: likely benign; called by muse, mutect2, varscan2
- BGN | c.975C>T p.F325= | Silent (SNP) | VAF 172/348 reads (49%) | catalogued as COSV59036685; called by muse, mutect2, varscan2
- CES4A | c.480C>T p.R160= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs1055518078, COSV58653637; called by muse, mutect2, varscan2
- CNTNAP2 | c.1857C>T p.S619= | Silent (SNP) | VAF 45/143 reads (31%) | catalogued as rs753699122, COSV62149673; called by muse, mutect2, varscan2
- DNAH2 | c.936G>A p.S312= | Silent (SNP) | VAF 35/90 reads (39%) | catalogued as rs1442133875, COSV50013187; called by muse, mutect2, varscan2
- FAM81B | c.465C>T p.L155= | Silent (SNP) | VAF 40/91 reads (44%) | catalogued as rs756519259, COSV51983325; called by muse, mutect2, varscan2
- GRM8 | c.1857C>T p.R619= | Silent (SNP) | VAF 33/111 reads (30%) | catalogued as COSV58805752, COSV58854595; called by muse, mutect2, varscan2
- KCNH3 | c.999G>T p.L333= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV57791027; called by muse, mutect2, varscan2
- MAMLD1 | c.927G>A p.A309= | Silent (SNP) | VAF 61/145 reads (42%) | catalogued as rs782260093, COSV53375476; called by muse, mutect2, varscan2
- MAP7D3 | c.1407T>C p.A469= | Silent (SNP) | VAF 70/175 reads (40%) | catalogued as COSV60171108; called by muse, mutect2, varscan2
- MUC4 | c.14490G>A p.Q4830= (on ENST00000463781 / NM_018406.7; = p.Q594= on NM_004532.6) | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV57782955; called by muse, mutect2, varscan2
- NPY5R | c.18C>T p.D6= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as rs371917653; called by muse, mutect2, varscan2
- OR51T1 | c.636C>T p.D212= | Silent (SNP) | VAF 39/92 reads (42%) | catalogued as rs138268565; called by muse, mutect2, varscan2
- PI4KA | c.4470G>A p.T1490= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as rs531119654, COSV55412301; called by muse, mutect2
- PTPRU | c.2277C>T p.L759= | Silent (SNP) | VAF 40/107 reads (37%) | catalogued as rs544754887, COSV60528687; called by muse, mutect2, varscan2
- SLC16A14 | c.174C>T p.N58= | Silent (SNP) | VAF 56/106 reads (53%) | catalogued as rs764784018, COSV54618901; called by muse, mutect2, varscan2
- TENM4 | c.7638A>G p.T2546= | Silent (SNP) | VAF 48/101 reads (48%) | catalogued as rs1307543673, COSV53632926; called by muse, mutect2, varscan2
- TGIF2LX | c.18C>T p.D6= | Silent (SNP) | VAF 35/81 reads (43%) | catalogued as rs372625687, COSV52213318; called by muse, mutect2, varscan2
- PFKFB2 | chr1:207078998 G>A | 3'Flank (SNP) | VAF 81/186 reads (44%) | catalogued as rs144692490; called by muse, mutect2, varscan2
